Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4697, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4697-01A (Primary Tumor).

FINAL DIAGNOSIS

RIGHT KIDNEY, NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN GRADE 4 OF 4, 14 CM IN GREATEST DIMENSION, WITH EXTENSIVE SARCOMATOID DEDIFFERENTIATION AND FOCAL NECROSIS.
- B. CARCINOMA INVADES INTO PERI-NEPHRIC ADIPOSE TISSUE ON THE LATERAL ASPECT OF THE KIDNEY.
- C. CARCINOMA DOES NOT INVADE ADIPOSE TISSUE ON THE MEDIAL ASPECT/RENAL SINUS ADIPOSE TISSUE.
- D. THE SURGICAL MARGIN ON GEROTA'S FASCIA IS FREE OF TUMOR; TUMOR EXTENDS TO WITHIN 0.1 CM OF THIS MARGIN.
- E. ANGIOLYMPHATIC INVASION IS PRESENT, REPRESENTED BY A TUMOR THROMBUS IN A MUSCLE-CONTAINING, BRANCH RENAL VEIN CLOSE TO THE HILUM.
- F. VASCULAR AND URETERAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. NON-NEOPLASTIC KIDNEY WITH NO SPECIFIC ABNORMALITY.
- H. PATHOLOGIC TNM STAGING: pT3b Nx Mx.

Source: NCI Genomic Data Commons file c9be8015-6cce-42a6-80cc-2218a5c0ec7c (TCGA-B0-4697.8C494270-BDB1-4D78-8127-88E3F90FB4AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).